Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A61A, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A61A-01A (Primary Tumor).

Pathology report for

Discussion:

Sections demonstrate many scattered MIB-1 reactive cells. In the most proliferative areas, a labeling index of 4.2% is calculated.

Diagnosis:

Oligodendroglioma, grade II

MIB-1 LI = 4.2%

Microscopic Description:

Sectioning demonstrate moderately hypercellular diffusely infiltrating glial neoplasm. The tumor cells have moderate atypia and round nuclei, most with perinuclear halos. No mitotic figures are seen. There is no microvascular proliferation or necrosis.

CSF ICD-O-3
Oligodendroglioma, grade II
path Oligodendroglioma NOS 9450/3
Site: Supratentorial NOS 9450/3
4/16/13

Distal Synchronous Primary Cited		
Case in (check)		

Source: NCI Genomic Data Commons file 4eb1d947-9d66-44fc-9454-97fe6d638027 (TCGA-HT-A61A.52DE6BC7-B83B-4C8A-AAAD-2B6D0AB0E614.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).